CGCI case BLGSP-71-23-00436 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74842c59-f213-41a4-b7af-52dd37bfe2f7

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 307 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 15.4 years (5,609 days); Year of diagnosis: 2016; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 287 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Pancreas, NOS / Small intestine.
   Pathology details: Lymph node involved site: Paraaortic; Tumor largest dimension diameter: 12 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 287 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD3 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- MYC: Normal.
- Lactate Dehydrogenase 3496 [Blood test normal range upper: 590].

Other clinical attributes
- Day 0: Comorbidities: Asthma.
- Day 0: Weight: 43 kg; Height: 107 cm; BMI: 37.6.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00436-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-23-00436-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 35; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00436-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00436-01-HE-1: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-BCL2: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-CD3: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-Ki67: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-CD20: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-CD10: Tissue microarray coordinates: B2,A5,D6.
  Slide BLGSP-71-23-00436-01-BCL6: Tissue microarray coordinates: B2,A5,D6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: History immunological disease other: Asthma / Bronchitis.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Pancreas; Extranodal involvement site: Small Intestine.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 3496; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
